Somatic mutation profile of tumor specimen MP2PRT-PASUDE-TMP1-A (aliquot MP2PRT-PASUDE-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASUDE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,732 days).
Specimen MP2PRT-PASUDE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e8ff5d6-ebed-460b-8c0c-a05a403b628e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASUDE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASUDE-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d6997c9-14a6-462b-98cb-b286dc4d581e

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGHV1-46 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1337425972; called by muse, varscan2
- RBMXL3 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 22/746 reads (3%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.84); catalogued as rs781912638, COSV100406329; called by muse, mutect2
- FRAS1 | c.9506T>A p.V3169E | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, varscan2
- IGHV1-46 | c.350_351insTTGGCCGGGGGTG p.R117Sfs*? | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | called by pindel, varscan2
- IGKV1OR2-108 | chr2:113406868 CCATTC>TTCA | Missense Mutation (DEL) | VAF 52/119 reads (44%) | called by pindel, varscan2*
- IGKV3-20 | chr2:89142573 GAGGTG>TGGGGGGA | Missense Mutation (INS) | VAF 56/166 reads (34%) | called by muse*, pindel
